Somatic mutation profile of tumor specimen MP2PRT-PAPHIJ-TMP1-A (aliquot MP2PRT-PAPHIJ-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PAPHIJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,384 days).
Specimen MP2PRT-PAPHIJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4dfbeca8-c742-4eea-a06f-76c8c84774e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPHIJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPHIJ-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3e3b51c-cc43-4718-95c5-76ebc349c429

The open-access MAF lists 36 somatic variants for this specimen: 20 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 19, Silent 16, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACIN1 | c.1772C>T p.S591L | Missense Mutation (SNP) | VAF 60/404 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99399870; called by muse, mutect2, varscan2
- ADAD1 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.506); catalogued as COSV56646364; called by muse, mutect2, varscan2
- AURKAIP1 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 87/386 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1196914068; called by muse, varscan2
- BBS10 | c.199A>G p.M67V | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as rs1161636895; called by muse, mutect2, varscan2
- CNGB1 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 57/335 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs780237166, COSV51898259; called by muse, mutect2, varscan2
- HYDIN | c.11495G>A p.R3832H | Missense Mutation (SNP) | VAF 36/284 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs7198721; called by muse, mutect2, varscan2
- KCNT1 | c.1037G>A p.R346H (on ENST00000488444; = p.R365H on NM_020822.3) | Missense Mutation (SNP) | VAF 82/417 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as rs1044487630, COSV53696606; called by muse, mutect2, varscan2
- LAMA2 | c.9014C>T p.A3005V | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs75048006, COSV70343885; called by muse, mutect2, varscan2
- OR4M1 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 72/836 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs752910596; called by muse, mutect2
- PIWIL2 | c.1733C>T p.T578I | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1435533414; called by muse, mutect2, varscan2
- PTH2R | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.05); catalogued as rs753279962, COSV55915312; called by muse, mutect2, varscan2
- SDK1 | c.6088G>A p.V2030I | Missense Mutation (SNP) | VAF 47/265 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.077); catalogued as rs150012421, COSV67389756; called by muse, mutect2, varscan2
- SLC9A7 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 51/412 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.166); catalogued as rs146304021, COSV60379286; called by muse, mutect2, varscan2
- ZNF469 | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 149/784 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1023475324; called by muse, mutect2, varscan2
- ZNF578 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.981); catalogued as COSV69736973; called by muse, mutect2, varscan2
- ARFGEF3 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 53/358 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- ATG16L2 | c.1643G>C p.G548A | Missense Mutation (SNP) | VAF 43/383 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- GUCY2F | c.2062G>A p.D688N | Missense Mutation (SNP) | VAF 50/458 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTCHD4 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 65/434 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TRAJ48 | c.1_6del p.S2_N3del | In Frame Del (DEL) | VAF 16/92 reads (17%) | called by pindel*, varscan2
- ADAD2 | c.30C>T p.D10= | Silent (SNP) | VAF 89/520 reads (17%) | catalogued as rs745480911, COSV51892514; called by muse, varscan2
- ANKRD7 | c.114G>A p.L38= | Silent (SNP) | VAF 42/196 reads (21%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.735C>T p.S245= | Silent (SNP) | VAF 52/354 reads (15%) | catalogued as rs777333205; called by muse, mutect2, varscan2
- CCSER2 | c.1194C>T p.S398= | Silent (SNP) | VAF 26/228 reads (11%) | catalogued as rs1221831089; called by muse, mutect2, varscan2
- CHST7 | c.222C>T p.A74= | Silent (SNP) | VAF 143/1067 reads (13%) | called by muse, mutect2, varscan2
- CRYBG3 | c.5406A>G p.V1802= | Silent (SNP) | VAF 43/280 reads (15%) | called by muse, mutect2, varscan2
- EGFR | c.966C>T p.G322= | Silent (SNP) | VAF 75/358 reads (21%) | catalogued as COSV51775450; called by muse, mutect2, varscan2
- GGT7 | c.966G>A p.P322= | Silent (SNP) | VAF 92/460 reads (20%) | catalogued as rs372405550; called by muse, mutect2, varscan2
- GOLGA8S | c.801G>A p.K267= | Silent (SNP) | VAF 20/178 reads (11%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1935C>T p.G645= | Silent (SNP) | VAF 108/661 reads (16%) | catalogued as rs753256738; ClinVar: likely benign; called by muse, varscan2
- KHDC1 | c.210G>A p.S70= | Silent (SNP) | VAF 25/144 reads (17%) | catalogued as rs377534797; called by muse, mutect2, varscan2
- LNPEP | c.2070C>T p.V690= | Silent (SNP) | VAF 30/191 reads (16%) | called by muse, mutect2, varscan2
- PCDHGB2 | c.1512C>T p.Y504= | Silent (SNP) | VAF 77/555 reads (14%) | catalogued as rs749825779, COSV54017062, COSV99545104; called by muse, mutect2, varscan2
- RMDN2 | c.240C>T p.N80= | Silent (SNP) | VAF 36/177 reads (20%) | catalogued as rs534843529; called by muse, mutect2, varscan2
- RTL9 | c.2220C>T p.T740= | Silent (SNP) | VAF 101/624 reads (16%) | catalogued as rs748004235; called by muse, mutect2, varscan2
- ZNF33B | c.1842T>C p.C614= | Silent (SNP) | VAF 50/321 reads (16%) | called by muse, mutect2, varscan2
